Somatic mutation profile of tumor specimen TARGET-40-NAAGJM-01A (aliquot TARGET-40-NAAGJM-01A-01D) from TARGET case TARGET-40-NAAGJM, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 5.8 years (2,132 days).
Specimen TARGET-40-NAAGJM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2177bf1e-9a33-4014-8afc-479224c9f14a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJM-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4178591-62e6-4746-a89e-cb3ec105e8cc

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH18 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56903476; called by muse, mutect2, varscan2
- TTBK2 | c.3281G>T p.R1094I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV51157293; called by muse, mutect2, varscan2
- CMYA5 | c.11501A>T p.E3834V | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RYR1 | c.8453C>G p.A2818G | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SNTG2 | c.104A>T p.E35V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZDHHC5 | c.461T>A p.L154H | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DUS3L | c.1053C>G p.A351= | Silent (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- HYDIN | c.9174G>A p.G3058= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, varscan2
- RPRD2 | c.861G>A p.V287= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, varscan2
- DCHS2 | n.3854G>A | RNA (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
